Surgical pathology report (de-identified scan), TCGA case TCGA-N8-A4PM, project TCGA-UCS (Uterine Carcinosarcoma), tissue source site University of North Carolina, specimen TCGA-N8-A4PM-01A (Primary Tumor).

[page 1 of 6]
SURGICAL PATHOLOGY

Case Number :

ICD O-3

Carcinosarcoma, NOS
8980/3

Site: Uterus,
Fundus Uteri
C54.3

Diagnosis:

A: Lymph node, right periaortic, excision

- No evidence of metastatic disease in nine lymph nodes (0/9)
with follicularlymphoid hyperplasia in lymph node examined at
frozen section

B: Uterus and cervix, hysterectomy:

Location of tumor: fundus

Histologic type: Carcinosarcoma (B6) with homologous sarcoma
component and endometrioid carcinoma with squamous
differentiation (20%) and serous carcinoma (80%).

Histologic grade (FIGO): FIGO grade 3

Extent of invasion: outer one half

Myometrial invasion: outer half

Depth: 1.0 cm Wall thickness: 1.6 cm

Percent: 63%

Serosal involvement: negative

Lower uterine segment involvement: negative

Cervical involvement: negative

Adnexal involvement (see below): negative

Other sites: negative

Cervical/vaginal margin and distance: widely negative

Lymphovascular space invasion: none seen

Regional lymph nodes (see other specimens):

Total number involved: 0

Total number examined: 25

Other pathologic findings: focal complex hyperplasia with atypia
of the endometrium and other areas of the endometrium with
atrophy

[page 2 of 6]
Tumor estrogen receptor and progesterone receptor immunohistochemistry results: Serous carcinoma component negative for both ER and PR (trace staining in 5% tumor nuclei) and endometrioid component positive for both ER and PR with 2-3+ staining in > 80% tumor nuclei

AJCC Pathologic Stage: pT1b pN0
FIGO (2008 classification) Stage grouping: IB

These stages are based on information available at the time of this report, and are subject to change pending additional information and clinical review.

Ovary, right, oophorectomy:

- Physiologic changes and small epithelial inclusion cysts

Ovary, left, oophorectomy:

- Physiologic changes and small epithelial inclusion cysts

Fallopian tube, right, salpingectomy:

- No significant pathologic abnormality

Fallopian tube, left, salpingectomy:

- No significant pathologic abnormality

C: Lymph node, left periaortic, dissection

- No evidence of metastatic disease in two lymph nodes (0/2)

D: Lymph node, right pelvic, dissection

- No evidence of metastatic disease in seven lymph nodes (0/7)

E: Lymph node, left pelvic, dissection

- No evidence of metastatic disease in seven lymph nodes (0/7)

Intraoperative Consult Diagnosis:

A frozen section was requested by Dr.

FSA1: Lymph node "right periaortic", excision

- Negative for metastatic disease
- Favor florid lymphoid hyperplasia

[page 3 of 6]
Drs. at

Frozen Section Pathologist:

Clinical History:

-year-old female with post menopausal bleeding, adenocarcinoma on PAP and endometrial biopsy with carcinosarcoma.

Gross Description:

Received are five appropriately labeled containers. Specimen A is received fresh for frozen section.

Specimen A is additionally labeled "right periaortic." It holds a 5.2 x 2.5 x 1.3 cm aggregate of bright yellow lobulated fat containing multiple lymph node candidates ranging from 0.3 to 2.3 cm in greatest dimension.

Block summary:

FSA1-FSA3 - largest lymph node candidate, serially sectioned
A4 - three lymph node candidates
A5 - three lymph node candidates
A6 - remainder of fibrofatty tissue,

Specimen B:

Adnexa: present and attached

Weight: 75 grams

Shape: pear shaped

Dimensions:

height: 7.1 cm

anterior to posterior width: 3.0 cm

breadth at fundus: 4.5 cm

Serosa: light tan, smooth and glistening

Cervix: 2.4 x 2.2 cm with a patent cervical os (0.4 cm)

ectocervix: predominantly light pink, smooth and glistening with focal punctate hemorrhage

endocervix: tan and trabeculated

length of endocervical canal: 1.7 cm

Endomyometrium:

length of endometrial cavity: 2.5 cm

width of endometrial cavity at fundus: 1.9 cm

tumor findings:

dimensions: 2.0 x 1.1 x 0.6 cm

appearance: The lesion is an exophytic thickening of the

[page 4 of 6]
endometrial lining at the fundus of the endometrial cavity. The proliferation is soft, brown and friable with an irregular surface.

location and extent: confined to the uterine fundus, greater than 2 cm from the endocervical canal

myometrial invasion: inner one-half

thickness of myometrial wall at deepest gross invasion: 1.6 cm

other findings or comments: none

Adnexa:

Right ovary:

dimensions: 1.6 x 1.0 x 0.5 cm

external surface: light pink and cerebriform

cut surface: tan and firm

Right fallopian tube:

dimensions: 2.1 cm long, 0.4 cm in diameter

other findings: The external surface is tan, smooth and glistening and the lumen is patent.

Left ovary:

dimensions: 1.4 x 1.1 x 0.7 cm

external surface: light pink and cerebriform

cut surface: tan and firm

Left fallopian tube:

dimensions: 2.6 cm long x 0.4 cm in diameter

other findings: The external surface is tan, smooth and glistening and the lumen is patent.

Lymph nodes: See Parts A, C-E of this case.

Other comments: none

Digital photograph taken: not taken

Tissue submitted for special investigations: A section of tumor is submitted for Tissue Procurement.

Block Summary:

B1 - anterior cervix and lower uterine segment

B2 - posterior cervix and lower uterine segment

B3 - tumor at deepest gross invasion

B4, B5 - additional sections of endomyometrium

B6, B7 - exophytic portion of lesion

B8 - uninvolved anterior endomyometrium

B9 - uninvolved posterior endomyometrium

B10 - right ovary and fallopian tube

B11 - left ovary and fallopian tube

[page 5 of 6]
Specimen C is additionally labeled "left periaortic." It holds a 3.5 x 1.9 x 1.0 cm aggregate of bright yellow lobulated fat containing a single firm tan lymph node candidate (1.6 x 0.8 x 0.6 cm). The lymph node candidate is serially sectioned and entirely submitted in block C1. The remainder of the specimen is submitted in blocks C2 and C3,

Specimen D is additionally labeled "right pelvic." It holds a 6.2 x 5.1 x 2.2 cm aggregate of bright yellow lobulated fat containing multiple lymph node candidates ranging from 0.6 to 2.2 cm in greatest dimension.

Block summary:

D1,D2 - largest lymph node candidate, serially sectioned
D3 - one lymph node candidate, bisected
D4 - one lymph node candidate, bisected
D5 - two lymph node candidates
D6 - two lymph node candidates
D7,D8 - remainder of fibrofatty tissue,

Container E is additionally labeled "Left pelvic." It holds a 5.6 x 3.7 x 2.5 cm aggregate of bright yellow lobulated fat containing multiple lymph node candidates ranging from 0.5 to 4.6 cm in greatest dimension.

Block summary:

E1-E4 - largest lymph node candidate, serially sectioned
E5-E7 - one lymph node, serially sectioned
E8 - four lymph node candidates
E9,E10 - remainder of fibrofatty tissue,

Grossing Pathologist:

Light Microscopy:

Light microscopic examination is performed by Dr.

For cases in which immunostains are performed, the following applies:

Appropriate internal and/or external positive and negative controls have been evaluated. Some of the immunohistochemical reagents used in this case may be classified as analyte specific reagents (ASR). These were developed and have performance characteristics determined by . These reagents have not been cleared or approved by the US Food and Drug Administration

Source: NCI Genomic Data Commons file d9b7c9ee-958c-4448-9892-194f4dbbd1f9 (TCGA-N8-A4PM.1DB40FDF-F0BD-495A-8DAA-B0FDE4BA5337.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).